Somatic mutation profile of tumor specimen BA2197D (aliquot aq-BA2197D) from BEATAML1.0 case 2308, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 50.6 years (18,475 days).
Specimen BA2197D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 704dc42e-5f74-4179-aee1-8144a247c074.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2740D (Solid Tissue Normal), aliquot aq-BA2740D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/820d6d69-3f91-4a18-a8dc-972d01171f66

The open-access MAF lists 44 somatic variants for this specimen: 35 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 7, Nonsense Mutation 4, Splice Site 2, Intron 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 48/134 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs121913503, COSV57468734, COSV57468971, COSV57472976; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 51/112 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APOB | c.1175C>A p.T392N | Missense Mutation (SNP) | VAF 90/208 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.439); catalogued as COSV51921981; called by muse, mutect2, varscan2
- ATP6V0A4 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 21/378 reads (6%) | SIFT tolerated (0.95); PolyPhen benign (0.356); catalogued as rs758193098; called by muse, mutect2
- CSMD1 | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs367545152, COSV68209530; called by muse, mutect2, varscan2
- FBN1 | c.6188C>T p.A2063V | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs1566896395, COSV57323753; called by muse, mutect2
- FMN1 | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.197); catalogued as rs972678254; called by muse, varscan2
- GANAB | c.997-1G>T p.X333_splice | Splice Site (SNP) | VAF 6/14 reads (43%) | catalogued as COSV60464367; called by mutect2, varscan2
- HMGCLL1 | c.775A>G p.M259V | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.332); catalogued as rs747609669; called by muse, mutect2, varscan2
- LRPAP1 | c.16G>A p.V6I | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as rs972906233; called by muse, mutect2, varscan2
- OR3A2 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 16/60 reads (27%) | catalogued as rs375263331; called by muse, varscan2
- POM121L12 | c.209G>T p.R70L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV68694177, COSV68694870; called by muse, mutect2, varscan2
- RARS2 | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV65761663; called by muse, mutect2
- RPS15A | c.95A>G p.K32R | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.167); catalogued as rs1452757570; called by muse, mutect2, varscan2
- SOX7 | c.1088C>T p.T363M | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.358); catalogued as rs773940037, COSV58731840; called by muse, mutect2, varscan2
- TEAD3 | c.811A>T p.I271F | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs921869763; called by muse, mutect2, varscan2
- TET2 | c.3866G>A p.C1289Y | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1382453941, COSV54396141, COSV54403681, COSV54405951, COSV54420752; called by muse, mutect2, varscan2
- CREBBP | c.4229T>C p.F1410S | Missense Mutation (SNP) | VAF 125/360 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CTAGE8 | c.2072C>A p.P691H | Missense Mutation (SNP) | VAF 36/407 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- LTBR | c.572G>A p.C191Y | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- MED12 | c.5945_5946insCCAAGCAC p.T1983Qfs*6 | Frame Shift Ins (INS) | VAF 14/47 reads (30%) | called by mutect2, pindel, varscan2
- MICAL3 | c.2892G>C p.K964N | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- MINDY3 | c.966C>G p.F322L | Missense Mutation (SNP) | VAF 12/181 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- MYO5A | c.1931A>G p.H644R | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- PLA2R1 | c.1670A>G p.E557G | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM10 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 20/37 reads (54%) | called by muse, mutect2, varscan2
- RBM47 | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- RPL10A | c.515T>G p.V172G | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, varscan2
- TSSK3 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 122/274 reads (45%) | called by muse, varscan2
- UCHL1 | c.526+1G>C p.X176_splice | Splice Site (SNP) | VAF 52/288 reads (18%) | called by muse, mutect2, varscan2
- UGT2B7 | c.44G>C p.S15T | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.031); called by muse, mutect2
- UNC13C | c.1739C>G p.S580* | Nonsense Mutation (SNP) | VAF 4/90 reads (4%) | called by muse, mutect2
- XRCC6 | c.1608dup p.E537* | Frame Shift Ins (INS) | VAF 30/131 reads (23%) | called by mutect2, pindel, varscan2
- ZNF165 | c.535C>A p.L179I | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.063); called by muse, mutect2
- ZNF827 | c.2517C>G p.H839Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ANTKMT | c.54G>A p.L18= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs1350240260; called by muse, mutect2
- ASXL3 | c.6516A>G p.E2172= | Silent (SNP) | VAF 43/89 reads (48%) | called by muse, mutect2, varscan2
- DNMT1 | c.2139G>A p.P713= | Silent (SNP) | VAF 25/808 reads (3%) | catalogued as rs1348393234; called by muse, mutect2
- MED13L | c.3069G>A p.T1023= | Silent (SNP) | VAF 65/148 reads (44%) | catalogued as rs780149328; ClinVar: benign; called by muse, mutect2, varscan2
- MYH8 | c.2733G>T p.L911= | Silent (SNP) | VAF 16/392 reads (4%) | called by muse, mutect2
- PNPO | c.40C>A p.R14= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- PRAMEF11 | c.636G>T p.V212= | Silent (SNP) | VAF 63/164 reads (38%) | called by muse, mutect2, varscan2
- MICAL3 | c.2242-774C>T | Intron (SNP) | VAF 94/207 reads (45%) | catalogued as COSV99262828; called by muse, mutect2, varscan2
- SYTL2 | c.1459+2286G>T | Intron (SNP) | VAF 8/109 reads (7%) | called by muse, mutect2
